CCDI case PBCGIZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/00f528e9-ebad-43ed-adb3-ba5aefab58ad

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Ileum; Age at diagnosis: 12.5 years (4,561 days).

Biospecimens (3 samples)
- Sample 0DSEYR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEZ4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSF00: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
